TCGA case TCGA-28-5211 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cf6689b9-d0fa-4461-a6b7-db477629e258

Demographics
Sex at birth: male; Race: black or african american; Age at index: 42 years; Vital status: Alive.

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 42.5 years (15,507 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: -1 day; Days to treatment end: 57 days; Number of cycles: 1; Treatment dose: 8,360 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 57 days; Treatment dose: 6,600 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 57 days; Treatment dose: 6,600 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 239 days; Days to treatment end: 307 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 239 days; Days to treatment end: 307 days; Number of cycles: 2; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 43.1 years (15,732 days); Days to diagnosis: 225 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.
3. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 43.1 years (15,732 days); Days to diagnosis: 225 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 225 (post initial treatment): Progression or recurrence: Yes; Days to progression: 225 days.
- Days to follow up: 358 days; Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-5211-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-28-5211-01C-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-28-5211-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Regimen number: 01; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 5: Regimen number: 02; Pharmaceutical therapy drug name: CPT11; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 358 days; disease-specific survival: no event (censored), 358 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 225 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-5211-01C-11D-1842-01): tumor purity 0.46, ploidy 1.99, whole-genome doublings 0.
